Somatic mutation profile of tumor specimen TCGA-13-1491-01A (aliquot TCGA-13-1491-01A-01W-0549-09) from TCGA case TCGA-13-1491, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 55.5 years (20,262 days).
Specimen TCGA-13-1491-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7f35c0b6-d5bb-4cd6-b134-0118bc4b9c58.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-1491-10A (Blood Derived Normal), aliquot TCGA-13-1491-10A-01W-0549-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1d43a5fd-7d4e-45ba-b416-aad81187974d

The open-access MAF lists 53 somatic variants for this specimen: 41 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 11, Nonsense Mutation 3, Frame Shift Del 1, Frame Shift Ins 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.824G>A p.C275Y | Missense Mutation (SNP) | VAF 75/100 reads (75%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.6856C>G p.L2286V | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.542); catalogued as COSV101330071; called by muse, mutect2
- ADCY2 | c.1597C>G p.H533D | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100602065, COSV57886318; called by muse, mutect2, varscan2
- AJAP1 | c.709A>G p.T237A | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.457); catalogued as COSV100981810; called by muse, mutect2, varscan2
- ANKRD17 | c.6939G>C p.Q2313H | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV58224488; called by muse, mutect2, varscan2
- BABAM1 | c.344G>T p.G115V | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV63921060, COSV63921216; called by muse, mutect2, varscan2
- BMT2 | c.356A>T p.D119V | Missense Mutation (SNP) | VAF 88/194 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV51779146; called by muse, varscan2
- CCDC63 | c.187A>C p.I63L | Missense Mutation (SNP) | VAF 34/47 reads (72%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.975); catalogued as COSV57529627; called by muse, mutect2, varscan2
- CDH18 | c.1120G>T p.V374F | Missense Mutation (SNP) | VAF 47/210 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1287507809, COSV56935740; called by muse, mutect2, varscan2
- CDH6 | c.2221G>A p.E741K | Missense Mutation (SNP) | VAF 73/164 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54074496; called by muse, mutect2, varscan2
- CHD8 | c.3844C>G p.L1282V (on ENST00000646647 / NM_001170629.2; = p.L1003V on NM_020920.4) | Missense Mutation (SNP) | VAF 91/230 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63219387; called by muse, mutect2, varscan2
- CLPP | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.104); catalogued as rs142079552; called by muse, mutect2, varscan2
- CRNN | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 43/212 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.092); catalogued as rs1469640842, COSV55122995; called by muse, mutect2, varscan2
- DNAH11 | c.11638A>C p.K3880Q | Missense Mutation (SNP) | VAF 91/196 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.949); catalogued as COSV60967598; called by muse, mutect2, varscan2
- DNAH5 | c.5071C>A p.H1691N | Missense Mutation (SNP) | VAF 60/139 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as COSV54240099; called by muse, mutect2, varscan2
- DSG1 | c.768C>A p.N256K | Missense Mutation (SNP) | VAF 58/155 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV57137652; called by muse, mutect2, varscan2
- DYNC1I1 | c.328G>T p.G110* | Nonsense Mutation (SNP) | VAF 44/170 reads (26%) | catalogued as COSV61466392; called by muse, mutect2, varscan2
- FGF10 | c.86T>G p.L29W | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.431); catalogued as COSV99240667; called by muse, mutect2
- FOXN3 | c.1301C>T p.T434I (on ENST00000261302; = p.T412I on NM_005197.4) | Missense Mutation (SNP) | VAF 60/161 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.3); catalogued as COSV54313338; called by muse, mutect2, varscan2
- GBP2 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 55/163 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV65069911; called by muse, mutect2, varscan2
- GRAMD4 | c.119T>A p.V40E | Missense Mutation (SNP) | VAF 29/33 reads (88%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV63031446; called by muse, mutect2, varscan2
- HLA-G | c.791C>T p.T264I | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV64406312; called by muse, varscan2
- ITGAX | c.1046T>A p.L349* | Nonsense Mutation (SNP) | VAF 35/42 reads (83%) | catalogued as COSV99191760; called by muse, mutect2, varscan2
- LRCH1 | c.1678T>A p.L560M | Missense Mutation (SNP) | VAF 111/216 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as COSV100243755; called by muse, mutect2, varscan2
- MDM4 | c.965G>C p.R322P | Missense Mutation (SNP) | VAF 21/255 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100914461, COSV65796259; called by muse, mutect2
- MOV10 | c.1678G>T p.A560S | Missense Mutation (SNP) | VAF 6/160 reads (4%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.836); catalogued as COSV100659603; called by muse, mutect2
- MPZL1 | c.202G>A p.G68R | Missense Mutation (SNP) | VAF 94/207 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs146968580; called by muse, mutect2, varscan2
- PCDH15 | c.5185C>G p.P1729A (on ENST00000644397 / NM_001354429.2; = p.P1671A on NM_001142771.2) | Missense Mutation (SNP) | VAF 13/205 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100903407, COSV100904782; called by muse, mutect2
- RNASEL | c.2059G>A p.D687N | Missense Mutation (SNP) | VAF 79/181 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.81); catalogued as rs1461968528, COSV62377455; called by muse, mutect2, varscan2
- RNF213 | c.13318G>A p.D4440N | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV60403798; called by muse, mutect2, varscan2
- ROBO1 | c.3185G>A p.R1062H | Missense Mutation (SNP) | VAF 77/159 reads (48%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.731); catalogued as rs770855014, COSV71392052; called by muse, mutect2, varscan2
- SCUBE1 | c.1726C>T p.Q576* | Nonsense Mutation (SNP) | VAF 11/15 reads (73%) | catalogued as COSV62614473; called by muse, mutect2, varscan2
- SLC12A2 | c.2142G>T p.W714C | Missense Mutation (SNP) | VAF 72/100 reads (72%) | SIFT deleterious (0.02); PolyPhen benign (0.286); catalogued as COSV52473087, COSV52474084; called by muse, mutect2, varscan2
- SRRT | c.2377C>A p.Q793K | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.682); catalogued as COSV53819725; called by muse, mutect2, varscan2
- SVIL | c.5656G>A p.V1886M (on ENST00000355867 / NM_021738.3; = p.V1460M on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as rs1406921284, COSV63445772; called by muse, mutect2, varscan2
- TPTE | c.925G>A p.V309I (on ENST00000618007 / NM_199261.4; = p.V291I on NM_199259.4) | Missense Mutation (SNP) | VAF 108/598 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); catalogued as rs373623566; called by muse, mutect2, varscan2
- VCAN | c.1732G>A p.E578K | Missense Mutation (SNP) | VAF 35/217 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99426097; called by muse, mutect2, varscan2
- ZNF407 | c.4944A>T p.K1648N | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55261686; called by muse, mutect2, varscan2
- C6orf47 | c.512dup p.E173Rfs*97 | Frame Shift Ins (INS) | VAF 10/108 reads (9%) | called by mutect2, pindel
- JARID2 | c.2370del p.F790Lfs*33 | Frame Shift Del (DEL) | VAF 4/35 reads (11%) | called by mutect2, pindel
- UFM1 | c.117+3_117+14del p.X39_splice | Splice Site (DEL) | VAF 55/146 reads (38%) | called by mutect2, pindel, varscan2
- ADD1 | c.1632C>T p.A544= | Silent (SNP) | VAF 30/38 reads (79%) | catalogued as rs763746024, COSV53271687; called by muse, mutect2, varscan2
- ARHGEF28 | c.537C>T p.S179= | Silent (SNP) | VAF 18/22 reads (82%) | catalogued as COSV55263616; called by muse, varscan2
- CTNNB1 | c.558C>T p.H186= | Silent (SNP) | VAF 73/78 reads (94%) | catalogued as rs373990577, COSV62709701; called by muse, mutect2, varscan2
- EHBP1 | c.1287T>C p.P429= | Silent (SNP) | VAF 286/689 reads (42%) | catalogued as COSV50427673; called by muse, mutect2, varscan2
- ERN2 | c.678C>T p.G226= | Silent (SNP) | VAF 12/17 reads (71%) | catalogued as rs756412528, COSV56831544; called by muse, varscan2
- GPR85 | c.972T>C p.A324= | Silent (SNP) | VAF 69/142 reads (49%) | catalogued as COSV51784570; called by muse, mutect2, varscan2
- IFI16 | c.2235G>A p.G745= (on ENST00000295809 / NM_001364867.2; = p.G689= on NM_005531.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 61/152 reads (40%) | catalogued as COSV55537069; called by muse, mutect2, varscan2
- IL16 | c.1734G>A p.P578= | Silent (SNP) | VAF 61/73 reads (84%) | catalogued as rs753258893, COSV57266281; called by muse, mutect2, varscan2
- OR8G1 | c.810G>A p.Q270= | Silent (SNP) | VAF 20/358 reads (6%) | catalogued as COSV100422453; called by muse, mutect2
- PELI3 | c.489C>T p.F163= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV57857246; called by muse, mutect2, varscan2
- TGIF2LX | c.18C>T p.D6= | Silent (SNP) | VAF 46/54 reads (85%) | catalogued as rs372625687, COSV52213318; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504216 ins GA | 5'Flank (INS) | VAF 19/61 reads (31%) | called by mutect2, pindel, varscan2
